Surgical pathology report (de-identified scan), TCGA case TCGA-32-2634, project TCGA-GBM (Glioblastoma Multiforme), tissue source site St. Joseph's Hospital (AZ), specimen TCGA-32-2634-01A (Primary Tumor).

NEUROPATHOLOGY REPORT

SPECIMEN SOURCE:

1. Left frontal brain tumor
2. Left frontal brain tumor
3. Left frontal brain tumor

GBM

Control

CLINICAL DIAGNOSIS:

Lobe mass

TCGA-32-2634

GROSS DESCRIPTION:

1. Received fresh for frozen section are two portions of tan-pink to red soft tissue aggregating to 0.3 x 0.2 x 0.1 cm. A smear preparation is performed. The specimen is entirely frozen on one chuck.

FROZEN SECTION DIAGNOSIS:

- PREDOMINANTLY NECROSIS WITH CLUSTER OF VIABLE CELLS.
- MALIGNANT NEOPLASM, FAVOR GLIOBLASTOMA.

GROSS DESCRIPTION:

The previously frozen tissue is subsequently submitted for permanent sections.

2. Received fresh for frozen section is a portion of tan-pink soft tissue measuring 0.8 x 0.6 cm. A smear preparation is performed. The specimen is entirely frozen on one chuck.

FROZEN SECTION DIAGNOSIS:

POORLY DIFFERENTIATED NEOPLASM CONSISTENT WITH GLIOBLASTOMA.

The previously frozen tissue is subsequently submitted for permanent sections.

3. Received in formalin labeled with the patient's name and "left frontal brain tumor" are multiple fragments of tan-white to pink-red soft tissue aggregating to 1.5 x 0.3 x 0.2 cm. Entirely submitted in one cassette.

MICROSCOPIC DESCRIPTION:

1-3. Sections demonstrate a high grade glial neoplasm consisting of a proliferation of atypical cells which resemble astrocytes. The tumor cells demonstrate oval to elongated hyperchromatic nuclei with moderate to marked atypia and prominent fibrillary processes. They diffusely infiltrate the adjacent brain parenchyma. Prominent necrosis, including serpentine pseudopalisading necrosis are present throughout the tumor. Robust microvascular proliferation is seen. There is a background of acute hemorrhage.

DIAGNOSIS:

(PROVISIONAL)

1-3. LEFT FRONTAL BRAIN TUMOR, BIOPSY AND RESECTION:

GLIOBLASTOMA (WHO GRADE IV), PENDING IMMUNOHISTOCHEMICAL STUDIES.

ADDENDUM NEUROPATHOLOGY REPORT

ADDENDUM DISCUSSION:

MGMT highlights numerous tumor vasculature. Overall, approximately 10-25% of the tumor cells express MGMT.

ADDENDUM DIAGNOSIS:

1-3. LEFT FRONTAL BRAIN TUMOR, BIOPSY AND RESECTION:

GLIOBLASTOMA (WHO GRADE IV).

- 10-25% OF TUMOR CELLS WITH MGMT EXPRESSION.

Source: NCI Genomic Data Commons file 78d8dcbc-c443-4874-8596-2d74f2072f88 (TCGA-32-2634.38156B43-7B5A-4D7F-AEF6-4922F6A2A690.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).